Somatic mutation profile of tumor specimen TCGA-EO-A3L0-01A (aliquot TCGA-EO-A3L0-01A-11D-A228-09) from TCGA case TCGA-EO-A3L0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.7 years (28,003 days).
Specimen TCGA-EO-A3L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94174736-e076-4eaa-9563-acd9f143b1fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3L0-10A (Blood Derived Normal), aliquot TCGA-EO-A3L0-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2469d186-5372-4b41-968f-96309d2efb74

The open-access MAF lists 93 somatic variants for this specimen: 72 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Frame Shift Del 9, Frame Shift Ins 5, Nonsense Mutation 4, Splice Region 2, Splice Site 1, Intron 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NAA10 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs797044868, COSV100892473, COSV64169548; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 47/102 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 34/60 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCL11B | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV100595583; called by muse, mutect2, varscan2
- BTNL8 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV99180488; called by muse, mutect2, varscan2
- C11orf65 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs369743303; called by muse, mutect2, varscan2
- C18orf25 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV99960057; called by mutect2, varscan2
- C8B | c.844A>C p.T282P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100980792; called by muse, mutect2, varscan2
- CADPS | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs141301525, COSV51881188; called by muse, mutect2, varscan2
- CCDC181 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs773563534, COSV63156807; called by muse, mutect2, varscan2
- CCDC39 | c.2230_2233del p.Q744Dfs*17 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs1313696540; called by pindel, varscan2
- CCKBR | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100582970; called by muse, mutect2, varscan2
- CDHR3 | c.2402G>A p.W801* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100488429, COSV100488847; called by muse, mutect2, varscan2
- CHL1 | c.1495G>C p.A499P (on ENST00000397491 / NM_001253387.1; = p.A515P on NM_006614.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV99851415; called by muse, mutect2, varscan2
- COL1A1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99867368; called by muse, mutect2, varscan2
- COL5A2 | c.3039G>A p.A1013= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs751945982, COSV100880421; ClinVar: likely benign; called by muse, mutect2, varscan2
- CUBN | c.10764C>A p.G3588= | Splice Region (SNP) | VAF 30/57 reads (53%) | catalogued as COSV100912809; called by muse, mutect2, varscan2
- DCLK1 | c.2096G>A p.R699Q (on ENST00000360631 / NM_001330072.2; = p.E724K on NM_004734.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.211); catalogued as COSV55199051, COSV99708982; called by muse, mutect2, varscan2
- DMBT1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.79); catalogued as COSV100353154; called by muse, mutect2, varscan2
- EPHB1 | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs774372100, COSV101213230; called by muse, mutect2, varscan2
- FNDC3B | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100394279; called by muse, mutect2, varscan2
- FRMPD4 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101043095; called by muse, mutect2, varscan2
- GRIN1 | c.1567C>A p.R523S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100160360; called by muse, mutect2, varscan2
- HHIPL2 | c.2104A>G p.S702G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100596908; called by muse, mutect2, varscan2
- IDS | c.405del p.V136Sfs*77 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as CM950664; called by pindel, varscan2
- IDS | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as CD982699; called by muse, varscan2
- LAMC3 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144930767, COSV63091766; called by muse, mutect2, varscan2
- LDB3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV99555057, COSV99555323; called by muse, mutect2, varscan2
- LMNA | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs372567202; called by muse, mutect2, varscan2
- LRP2 | c.5084C>T p.S1695L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs767944750, COSV55573172; called by muse, mutect2, varscan2
- MCOLN2 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99393951; called by muse, mutect2, varscan2
- MROH7 | c.3352C>G p.P1118A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as COSV100273590; called by muse, mutect2
- MRPS10 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs752286039, COSV99273585; called by muse, mutect2, varscan2
- MXRA5 | c.7228C>T p.R2410C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs866456166, COSV99477221; called by muse, mutect2, varscan2
- NKAP | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57631113; called by muse, mutect2, varscan2
- NOTCH1 | c.845del p.R282Pfs*20 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | catalogued as COSV99490413; called by mutect2, pindel, varscan2
- NPAT | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs763440042, COSV53720768, COSV99586079; called by muse, mutect2, varscan2
- OR10AG1 | c.626A>T p.Y209F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100400104; called by muse, mutect2, varscan2
- OR13A1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.163); catalogued as COSV100981043; called by muse, mutect2, varscan2
- PGAM4 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV58453567; called by muse, mutect2, varscan2
- PLOD2 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1436248248, COSV99282837; called by muse, mutect2
- PPP6R3 | c.1376G>T p.G459V (on ENST00000393800 / NM_001352375.2; = p.G408V on NM_018312.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676641; called by muse, mutect2, varscan2
- PTEN | c.221dup p.H75Tfs*3 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as COSV64290598; called by mutect2, pindel, varscan2
- PTPRZ1 | c.144T>A p.N48K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV66440178; called by muse, mutect2
- RBP3 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs782681548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6KA6 | c.1431T>A p.H477Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99424848; called by muse, mutect2, varscan2
- SETDB1 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977297; called by muse, mutect2, varscan2
- SGSM3 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs201695534, COSV50651261; called by muse, mutect2, varscan2
- SOWAHB | c.1921C>A p.H641N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100530714; called by muse, mutect2
- STS | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99481319; called by muse, mutect2, varscan2
- THOC6 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99560641; called by muse, mutect2, varscan2
- TMPO | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV99702048; called by muse, mutect2, varscan2
- TSPOAP1 | c.1947C>A p.S649R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV99271261; called by muse, mutect2
- UBASH3A | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs753503071, COSV52315916; called by muse, mutect2, varscan2
- ZNF707 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs782599386, COSV100690633; called by muse, mutect2
- ZNF799 | c.974A>C p.Q325P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101345268; called by muse, mutect2, varscan2
- AGR2 | c.38dup p.A14Gfs*37 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.5619del p.C1874Afs*9 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- C3 | c.3519dup p.D1174Rfs*4 | Frame Shift Ins (INS) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- CDK1 | c.889_894del p.M297_*298delext*40 | Nonstop Mutation (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- CNDP1 | c.975_990del p.V326Sfs*8 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- JUN | c.667dup p.Q223Pfs*87 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel
- LOXL4 | c.1962_1963insATTGCAGCGG p.R655Ifs*26 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- NUMA1 | c.5392_5404del p.L1798Vfs*18 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, varscan2
- RTP2 | c.252_255del p.G85Rfs*91 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- SETDB1 | c.3159_3160del p.X1053_splice | Splice Site (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- TM4SF20 | c.327_328del p.L110Kfs*7 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by pindel, varscan2
- ZCCHC7 | c.884_902delinsGT p.S295Cfs*4 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by pindel, varscan2*
- A2M | c.3630C>T p.S1210= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV59392207; called by muse, mutect2, varscan2
- ATP1A3 | c.900C>A p.G300= (on ENST00000545399 / NM_001256214.2; = p.G287= on NM_152296.5) | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- DAGLA | c.1191C>T p.I397= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99944437; called by muse, mutect2, varscan2
- DENND5A | c.2589C>G p.S863= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100064779, COSV60238213; called by muse, mutect2, varscan2
- DYTN | c.219C>G p.A73= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV101510846; called by muse, mutect2, varscan2
- GBGT1 | c.459C>T p.A153= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs778788525, COSV100923776; called by muse, mutect2, varscan2
- IRX1 | c.399C>T p.N133= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV57361024; called by muse, mutect2, varscan2
- KCNA1 | c.360C>T p.Y120= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs528107023, COSV101230283; called by muse, mutect2, varscan2
- MAML3 | c.594G>A p.A198= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs530563778, COSV100505207; called by muse, mutect2, varscan2
- MYPOP | c.27G>A p.A9= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100447875; called by muse, mutect2
- MYT1L | c.1527T>C p.C509= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV101220563, COSV101220905; called by muse, mutect2, varscan2
- NAPEPLD | c.369T>C p.A123= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100439878; called by muse, mutect2, varscan2
- OR4C6 | c.363C>T p.Y121= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs141756140; called by muse, mutect2, varscan2
- PKD1 | c.7941G>A p.T2647= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs573381520, COSV99238263; called by muse, mutect2, varscan2
- PSD | c.78C>T p.L26= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1168360121, COSV99192782; called by muse, mutect2, varscan2
- RHOBTB2 | c.927G>A p.S309= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52572340; called by muse, mutect2, varscan2
- SP110 | c.558C>T p.L186= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99283482; called by muse, mutect2, varscan2
- USP19 | c.3771G>A p.P1257= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs371843224, COSV100070064; called by muse, mutect2, varscan2
- ZNF668 | c.1506C>T p.G502= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV56213737; called by muse, mutect2, varscan2
- ADD2 | c.1742-306C>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs199710132; called by muse, mutect2, varscan2
- SLC22A20P | n.1224C>T | RNA (SNP) | VAF 7/27 reads (26%) | catalogued as rs762535336; called by muse, mutect2, varscan2
